Somatic mutation profile of cancer-model specimen HCM-SANG-0313-C15-85A (3D Organoid; aliquot HCM-SANG-0313-C15-85A-01D-A78J-36), derived from the primary tumor of HCMI case HCM-SANG-0313-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS.
Specimen HCM-SANG-0313-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5af4cd67-d979-4540-89a0-9e8faa4da49f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0313-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0313-C15-10A-01D-A78J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d428fd50-f98c-4be9-9319-48068663179c

The open-access MAF lists 181 somatic variants for this specimen: 136 protein-altering or splice-affecting, 33 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 33, Splice Site 5, Frame Shift Del 5, Intron 4, In Frame Del 3, 5'UTR 3, Nonsense Mutation 3, 3'UTR 2, RNA 2, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 142/145 reads (98%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PAH | c.441+1G>A p.X147_splice | Splice Site (SNP) | VAF 177/442 reads (40%) | catalogued as rs62517166, CS139535, CS951498; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PDX1 | c.217dup p.L73Pfs*152 | Frame Shift Ins (INS) | VAF 106/481 reads (22%) | catalogued as rs1445970498; ClinVar: pathogenic; called by mutect2, varscan2
- PKD2 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 258/445 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553925453, CM020955, CM163930, COSV99417179; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.748_756del p.P250_L252del | In Frame Del (DEL) | VAF 194/210 reads (92%) | hotspot (GDC flag); catalogued as COSV52871148; called by mutect2, pindel, varscan2
- ATRNL1 | c.2250A>C p.E750D | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100746756; called by muse, mutect2, varscan2
- BCL6B | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 178/179 reads (99%) | SIFT tolerated (0.16); PolyPhen benign (0.098); catalogued as COSV53427305; called by muse, mutect2, varscan2
- C7orf31 | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 65/359 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs1405518985, COSV52219788; called by muse, mutect2, varscan2
- CALD1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 65/106 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100724468; called by muse, mutect2, varscan2
- CCDC127 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 165/526 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs766544426, COSV99722892; called by muse, mutect2, varscan2
- CCR7 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs1365219236, COSV55850218; called by muse, mutect2, varscan2
- CDO1 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as rs1157991434, COSV99164782; called by muse, mutect2, varscan2
- CNBD2 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 80/389 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs539557197, COSV62588051; called by muse, mutect2, varscan2
- CNTN6 | c.220A>G p.S74G | Missense Mutation (SNP) | VAF 217/217 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV63160327, COSV63180477; called by muse, mutect2, varscan2
- COL9A3 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 265/522 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs952982296, COSV59650183, COSV59651792; called by muse, mutect2, varscan2
- CPAMD8 | c.3404G>A p.R1135Q (on ENST00000651564; = p.R1088Q on NM_015692.5) | Missense Mutation (SNP) | VAF 413/413 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs61742969, COSV71595756; called by muse, mutect2, varscan2
- CRHR2 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59268627; called by muse, mutect2
- DHX15 | c.2090A>G p.Y697C | Missense Mutation (SNP) | VAF 53/72 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1342070899, COSV61028385; called by muse, mutect2, varscan2
- DNAH11 | c.10256C>G p.S3419C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs776561202; called by muse, mutect2, varscan2
- DSG3 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57126293; called by muse, mutect2, varscan2
- EPHA5 | c.1832C>A p.A611D | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.981); catalogued as COSV99900650; called by muse, mutect2, varscan2
- FAT2 | c.12632C>G p.S4211* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV55827055; called by muse, mutect2
- FBN3 | c.2743G>C p.E915Q | Missense Mutation (SNP) | VAF 173/173 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54454630; called by muse, mutect2, varscan2
- GAREM2 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 12/393 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101293708; called by muse, mutect2
- GCNA | c.570C>G p.D190E | Missense Mutation (SNP) | VAF 326/632 reads (52%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs1437621461; called by muse, varscan2
- HAT1 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 59/103 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.249); catalogued as rs371624911; called by muse, mutect2, varscan2
- HECW2 | c.4385G>C p.R1462T | Missense Mutation (SNP) | VAF 78/234 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99649176; called by muse, mutect2, varscan2
- IGLV2-23 | c.179A>G p.H60R | Missense Mutation (SNP) | VAF 179/415 reads (43%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as rs781754135; called by muse, mutect2, varscan2
- KCNB2 | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 243/451 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73050299; called by muse, mutect2, varscan2
- LRRC43 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs758270208, COSV60288782; called by muse, mutect2, varscan2
- NBEA | c.974G>T p.W325L | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59776252; called by muse, mutect2
- NCOR2 | c.4016G>A p.R1339Q | Missense Mutation (SNP) | VAF 102/195 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs757239625; called by muse, mutect2, varscan2
- NEUROG3 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 17/565 reads (3%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.781); catalogued as rs1183956275; called by muse, mutect2
- NOTCH1 | c.3055C>A p.Q1019K | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV53032816; called by muse, mutect2
- OR4A15 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 263/266 reads (99%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.024); catalogued as rs749602827, COSV59033477, COSV59034320; called by muse, mutect2, varscan2
- OR52H1 | c.794G>A p.R265H (on ENST00000322653; = p.R271H on NM_001005289.1) | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs143065051; called by muse, mutect2, varscan2
- OR6C2 | c.649T>G p.L217V | Missense Mutation (SNP) | VAF 264/398 reads (66%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV59515470; called by muse, mutect2, varscan2
- PAK4 | c.1544A>G p.Y515C | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1282615550; called by muse, mutect2, varscan2
- POU6F2 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as COSV68884828; called by muse, mutect2
- RUSC2 | c.3877C>G p.R1293G | Missense Mutation (SNP) | VAF 415/416 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV63427711; called by muse, mutect2, varscan2
- RYR2 | c.3645G>A p.M1215I | Missense Mutation (SNP) | VAF 85/279 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV63685913, COSV63711088; called by muse, mutect2, varscan2
- SELPLG | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 129/257 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776843709, COSV57312605; called by muse, mutect2, varscan2
- SERPINA9 | c.602T>G p.V201G | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1216079990; called by muse, mutect2, varscan2
- SLIT1 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 223/319 reads (70%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs753340975; called by muse, mutect2, varscan2
- SSH1 | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 17/303 reads (6%) | catalogued as COSV58454639; called by muse, mutect2
- TCERG1L | c.1445A>G p.D482G | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763029060; called by muse, mutect2, varscan2
- TRAT1 | c.462C>A p.D154E | Missense Mutation (SNP) | VAF 250/251 reads (100%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as COSV99849521; called by muse, mutect2, varscan2
- UBE2H | c.221T>A p.I74N | Missense Mutation (SNP) | VAF 87/143 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62920406; called by muse, mutect2, varscan2
- VTN | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as rs782542357, COSV56873436; called by muse, mutect2
- ZBTB7C | c.1715dup p.L573Pfs*80 | Frame Shift Ins (INS) | VAF 116/881 reads (13%) | catalogued as rs1197932708; called by mutect2, pindel, varscan2
- ZNF134 | c.1088A>G p.Q363R | Missense Mutation (SNP) | VAF 426/428 reads (100%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.929); catalogued as COSV104432797; called by muse, mutect2, varscan2
- ZNF638 | c.4914T>A p.N1638K | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as rs762586567, COSV52490158; called by muse, mutect2, varscan2
- AC100868.1 | c.1098A>G p.I366M | Missense Mutation (SNP) | VAF 327/680 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- ADAMTS18 | c.1448A>T p.K483M | Missense Mutation (SNP) | VAF 275/275 reads (100%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ADGRB2 | c.2941A>G p.I981V | Missense Mutation (SNP) | VAF 118/335 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ADRA2A | c.1313C>G p.P438R | Missense Mutation (SNP) | VAF 20/552 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AGO3 | c.52C>G p.P18A | Missense Mutation (SNP) | VAF 133/193 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- AP1M1 | c.986T>G p.V329G | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ARHGEF10L | c.3779A>G p.Q1260R | Missense Mutation (SNP) | VAF 117/166 reads (70%) | SIFT tolerated (0.39); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ARID1B | c.5067A>T p.E1689D | Missense Mutation (SNP) | VAF 336/652 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ASXL3 | c.4006A>C p.T1336P | Missense Mutation (SNP) | VAF 39/289 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BICD2 | c.1622T>A p.V541E | Missense Mutation (SNP) | VAF 162/308 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2818T>G p.F940V | Missense Mutation (SNP) | VAF 332/334 reads (99%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BLK | c.1417T>C p.W473R | Missense Mutation (SNP) | VAF 236/407 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C2orf16 | c.946T>G p.L316V | Missense Mutation (SNP) | VAF 158/383 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- CACNG8 | c.938C>A p.P313H | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- CAGE1 | c.933A>T p.K311N (on ENST00000512086; = p.K175N on NM_205864.3) | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CALD1 | c.2371A>G p.T791A (on ENST00000361675 / NM_033138.4; = p.T536A on NM_004342.7) | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CCDC141 | c.2886A>C p.E962D | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CDH9 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 88/362 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CFAP61 | c.1309T>G p.F437V | Missense Mutation (SNP) | VAF 137/358 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHL1 | c.2560del p.S854Vfs*12 (on ENST00000397491 / NM_001253387.1; = p.S870Vfs*12 on NM_006614.4) | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | called by mutect2, pindel, varscan2
- CHL1 | c.2557A>C p.K853Q (on ENST00000397491 / NM_001253387.1; = p.K869Q on NM_006614.4) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.052); called by mutect2, varscan2
- COL6A1 | c.1740+2_1740+3del p.X580_splice | Splice Site (DEL) | VAF 93/194 reads (48%) | called by mutect2, pindel*, varscan2*
- COQ8B | c.1566T>A p.S522R | Missense Mutation (SNP) | VAF 110/306 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDR1 | c.2131C>G p.Q711E (on ENST00000324771; = p.Q674E on NM_001954.4) | Missense Mutation (SNP) | VAF 103/375 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DISC1 | c.1483C>A p.Q495K | Missense Mutation (SNP) | VAF 256/428 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DNAAF5 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 79/154 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ENTR1 | c.745A>T p.S249C (on ENST00000357365 / NM_001039707.2; = p.S226C on NM_006643.4) | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- FSIP2 | c.12755A>C p.Q4252P | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- FUBP1 | c.1041+1G>A p.X347_splice | Splice Site (SNP) | VAF 127/214 reads (59%) | called by muse, mutect2, varscan2
- GCC2 | c.108A>T p.K36N | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GREB1L | c.2138C>T p.S713L | Missense Mutation (SNP) | VAF 281/902 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRIN2D | c.256C>G p.P86A | Missense Mutation (SNP) | VAF 141/142 reads (99%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- HERC1 | c.9992A>C p.N3331T | Missense Mutation (SNP) | VAF 228/229 reads (100%) | SIFT tolerated (1); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- HSPB8 | c.195G>T p.R65S | Missense Mutation (SNP) | VAF 129/276 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- IL1R1 | c.616_618del p.Q206del | In Frame Del (DEL) | VAF 22/124 reads (18%) | called by pindel, varscan2
- IL20RA | c.535C>A p.L179M | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.871); called by muse, mutect2
- IQCA1 | c.130A>C p.T44P | Missense Mutation (SNP) | VAF 175/279 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- IQGAP2 | c.4244_4251del p.K1415Ifs*12 | Frame Shift Del (DEL) | VAF 70/146 reads (48%) | called by mutect2, pindel, varscan2
- LHX5 | c.623A>G p.H208R | Missense Mutation (SNP) | VAF 96/208 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- LOXHD1 | c.4738A>G p.K1580E | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- LOXHD1 | c.4267G>A p.D1423N | Missense Mutation (SNP) | VAF 250/401 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRRC4C | c.83T>C p.V28A | Missense Mutation (SNP) | VAF 149/149 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEA10 | c.450A>C p.Q150H | Missense Mutation (SNP) | VAF 57/57 reads (100%) | SIFT tolerated (0.37); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MAGEA8 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- MAGEE1 | c.2771A>C p.K924T | Missense Mutation (SNP) | VAF 163/163 reads (100%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- MAK16 | c.543_546del p.F181Lfs*45 | Frame Shift Del (DEL) | VAF 42/88 reads (48%) | called by mutect2, pindel, varscan2
- MAML2 | c.326C>A p.P109H | Missense Mutation (SNP) | VAF 7/185 reads (4%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.557); called by muse, mutect2
- MAZ | c.741del p.G249Efs*18 | Frame Shift Del (DEL) | VAF 26/118 reads (22%) | called by mutect2, pindel, varscan2
- MLX | c.353A>G p.H118R | Missense Mutation (SNP) | VAF 85/302 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC6 | c.4284_4302del p.H1428Qfs*22 | Frame Shift Del (DEL) | VAF 118/588 reads (20%) | called by pindel, varscan2
- NEFL | c.301T>C p.F101L | Missense Mutation (SNP) | VAF 265/266 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP14 | c.2680A>T p.T894S | Missense Mutation (SNP) | VAF 34/696 reads (5%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2
- NME8 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 32/541 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.378); called by muse, mutect2
- NRXN1 | c.875_877del p.F292del | In Frame Del (DEL) | VAF 28/108 reads (26%) | called by mutect2, pindel
- ODAPH | c.72A>C p.Q24H | Missense Mutation (SNP) | VAF 92/376 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- OMD | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 160/161 reads (99%) | SIFT deleterious (0.03); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- PIGN | c.2497T>C p.W833R | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PLEC | c.13876T>A p.S4626T (on ENST00000322810 / NM_201380.4; = p.S4516T on NM_000445.5) | Missense Mutation (SNP) | VAF 186/816 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PPP1R1A | c.299A>G p.E100G | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PRAMEF20 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 35/676 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2
- PTPN18 | c.481C>T p.L161= | Splice Region (SNP) | VAF 54/143 reads (38%) | called by muse, mutect2, varscan2
- PTPRC | c.2227C>G p.Q743E | Missense Mutation (SNP) | VAF 115/377 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- R3HCC1L | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- RFPL4B | c.48T>A p.D16E | Missense Mutation (SNP) | VAF 114/114 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RHOJ | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 111/219 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RPH3A | c.449G>T p.W150L (on ENST00000389385 / NM_001143854.2; = p.W146L on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RPL37A | c.132+1G>T p.X44_splice | Splice Site (SNP) | VAF 66/141 reads (47%) | called by muse, mutect2, varscan2
- SF3B4 | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- SLC22A31 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- SPATA21 | c.529A>G p.R177G | Missense Mutation (SNP) | VAF 120/428 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- SRSF4 | c.108-1G>T p.X36_splice | Splice Site (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- SULT2A1 | c.836G>C p.R279P | Missense Mutation (SNP) | VAF 199/304 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF2 | c.817C>A p.L273I | Missense Mutation (SNP) | VAF 106/413 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TENM3 | c.4514T>G p.L1505R | Missense Mutation (SNP) | VAF 285/285 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- TFB1M | c.713T>C p.I238T | Missense Mutation (SNP) | VAF 387/821 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- TMED1 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 102/102 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMPRSS15 | c.2459T>C p.L820P | Missense Mutation (SNP) | VAF 233/233 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TOPAZ1 | c.2915A>C p.D972A | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.242); called by muse, mutect2
- TTN | c.62610A>C p.K20870N (on ENST00000591111; = p.K13446N on NM_003319.4) | Missense Mutation (SNP) | VAF 117/388 reads (30%) | PolyPhen benign (0.116); called by muse, mutect2, varscan2
- U2AF2 | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB38 | c.3314A>G p.Y1105C | Missense Mutation (SNP) | VAF 249/249 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF117 | c.305G>C p.R102T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2
- ZNF672 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2
- ZNF729 | c.2113A>C p.I705L | Missense Mutation (SNP) | VAF 124/293 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, varscan2
- ANAPC5 | c.2160C>G p.L720= | Silent (SNP) | VAF 19/522 reads (4%) | called by muse, mutect2
- COLEC11 | c.492G>A p.A164= | Silent (SNP) | VAF 301/708 reads (43%) | catalogued as rs138441935, COSV52596739; called by muse, mutect2, varscan2
- CPNE8 | c.918G>C p.T306= | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as COSV58841117; called by muse, mutect2, varscan2
- DIAPH2 | c.843T>C p.A281= | Silent (SNP) | VAF 133/133 reads (100%) | called by muse, mutect2, varscan2
- ENTR1 | c.744T>C p.P248= (on ENST00000357365 / NM_001039707.2; = p.P225= on NM_006643.4) | Silent (SNP) | VAF 23/164 reads (14%) | called by muse, mutect2, varscan2
- FBN3 | c.4503C>T p.D1501= | Silent (SNP) | VAF 10/218 reads (5%) | catalogued as COSV54476250; called by muse, mutect2
- IKZF3 | c.741G>A p.E247= | Silent (SNP) | VAF 53/679 reads (8%) | called by muse, mutect2
- KIAA0825 | c.489T>C p.D163= | Silent (SNP) | VAF 218/218 reads (100%) | called by muse, mutect2, varscan2
- LIAS | c.27C>T p.A9= | Silent (SNP) | VAF 158/237 reads (67%) | catalogued as rs553110956; called by muse, mutect2, varscan2
- LMOD3 | c.1608T>C p.D536= | Silent (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2
- MROH2A | c.1176C>T p.F392= | Silent (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
- MUC16 | c.35718T>C p.S11906= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs956634978; called by muse, mutect2, varscan2
- MUC16 | c.30840T>G p.P10280= | Silent (SNP) | VAF 59/59 reads (100%) | called by muse, mutect2, varscan2
- MYO5B | c.3477G>A p.E1159= | Silent (SNP) | VAF 94/1054 reads (9%) | called by muse, mutect2
- OR5R1 | c.489T>C p.T163= | Silent (SNP) | VAF 92/185 reads (50%) | catalogued as COSV56571442; called by muse, mutect2, varscan2
- OR6B2 | c.81C>A p.L27= | Silent (SNP) | VAF 53/320 reads (17%) | catalogued as COSV53152994; called by muse, varscan2
- OR6B3 | c.81C>A p.L27= | Silent (SNP) | VAF 100/195 reads (51%) | called by muse, mutect2, varscan2
- PHF10 | c.117G>T p.G39= | Silent (SNP) | VAF 173/379 reads (46%) | called by muse, mutect2, varscan2
- PTPRB | c.3996C>T p.V1332= | Silent (SNP) | VAF 115/397 reads (29%) | catalogued as COSV99716119; called by muse, mutect2, varscan2
- RBM20 | c.2358C>T p.D786= | Silent (SNP) | VAF 79/214 reads (37%) | catalogued as rs1045844360; ClinVar: likely benign; called by muse, mutect2, varscan2
- RHOU | c.435G>C p.P145= | Silent (SNP) | VAF 160/656 reads (24%) | catalogued as COSV64208357; called by muse, mutect2, varscan2
- RNF169 | c.2115C>T p.A705= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as rs71465936, COSV100213668; called by muse, mutect2
- SHROOM3 | c.3150G>A p.P1050= | Silent (SNP) | VAF 174/455 reads (38%) | catalogued as rs746539386; called by muse, mutect2
- SOX3 | c.1086A>T p.A362= | Silent (SNP) | VAF 75/75 reads (100%) | called by muse, mutect2, varscan2
- SS18L1 | c.15C>T p.F5= | Silent (SNP) | VAF 98/352 reads (28%) | called by muse, mutect2, varscan2
- STAM2 | c.960G>A p.L320= | Silent (SNP) | VAF 312/442 reads (71%) | called by muse, mutect2, varscan2
- SYNE2 | c.12759A>G p.Q4253= | Silent (SNP) | VAF 81/550 reads (15%) | catalogued as rs754138105; called by muse, mutect2, varscan2
- TENM2 | c.6105T>C p.S2035= (on ENST00000518659 / NM_001122679.2; = p.S1796= on NM_001080428.3) | Silent (SNP) | VAF 125/299 reads (42%) | called by muse, mutect2, varscan2
- TMEM131L | c.2541G>A p.V847= | Silent (SNP) | VAF 129/407 reads (32%) | called by muse, mutect2, varscan2
- TRIM64C | c.33T>C p.N11= | Silent (SNP) | VAF 189/189 reads (100%) | called by muse, mutect2, varscan2
- TRRAP | c.2946C>T p.H982= | Silent (SNP) | VAF 67/180 reads (37%) | catalogued as rs782750766; called by muse, mutect2, varscan2
- WEE2 | c.1557G>A p.Q519= | Silent (SNP) | VAF 136/492 reads (28%) | catalogued as rs1467719602; called by muse, mutect2, varscan2
- ZNF554 | c.1410G>C p.G470= | Silent (SNP) | VAF 185/186 reads (99%) | called by muse, mutect2, varscan2
- AC104078.1 | n.298dup | RNA (INS) | VAF 46/186 reads (25%) | catalogued as rs762277152; called by mutect2, varscan2
- AC138969.1 | chr16:16326917 A>C | 5'Flank (SNP) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- BBS5 | c.*3G>A | 3'UTR (SNP) | VAF 79/312 reads (25%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+3380C>A | Intron (SNP) | VAF 108/304 reads (36%) | called by muse, mutect2, varscan2
- FAM20A | c.*1605A>G | 3'UTR (SNP) | VAF 160/261 reads (61%) | called by muse, mutect2, varscan2
- HTN1 | c.-9C>G | 5'UTR (SNP) | VAF 25/166 reads (15%) | called by muse, mutect2, varscan2
- MAN2B2 | c.-7C>G | 5'UTR (SNP) | VAF 108/322 reads (34%) | catalogued as rs1270807008; called by muse, mutect2, varscan2
- MUC6 | c.53-112_53-111insT | Intron (INS) | VAF 44/119 reads (37%) | called by mutect2, pindel, varscan2
- NDUFA4 | c.-50G>C | 5'UTR (SNP) | VAF 216/390 reads (55%) | catalogued as rs1482648420; called by muse, mutect2, varscan2
- OR5E1P | n.742G>A | RNA (SNP) | VAF 229/491 reads (47%) | catalogued as rs1043765023; called by muse, mutect2, varscan2
- TTN | c.34523-317T>A | Intron (SNP) | VAF 18/138 reads (13%) | catalogued as rs979855817, COSV60048234; called by muse, varscan2
- TTN | c.10361-3966T>C | Intron (SNP) | VAF 35/58 reads (60%) | called by muse, mutect2, varscan2
